MMRF case MMRF_1744 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d4231152-3b94-4905-ab86-dec60f2982a2

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 68.4 years (24,968 days); Days to last known disease status: 1,098 days (3.0 years); Days to last follow up: 1,098 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 874 days (2.4 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 321 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 854 days (2.3 years).
   Treatment given: Therapeutic agents: Thalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 30 days; Days to treatment end: 37 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: First line of therapy; Days to treatment start: 43 days; Days to treatment end: 64 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 120 days; Days to treatment end: 854 days (2.3 years).
   Treatment given: Therapeutic agents: Elotuzumab; Regimen or line of therapy: First line of therapy; Days to treatment start: 727 days (2.0 years); Days to treatment end: 867 days (2.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 875 days (2.4 years); Days to treatment end: 1,156 days (3.2 years).
   Treatment given: Therapeutic agents: Daratumumab; Regimen or line of therapy: Second line of therapy; Days to treatment start: 884 days (2.4 years); Days to treatment end: 1,128 days (3.1 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 885 days (2.4 years); Days to treatment end: 947 days (2.6 years).
   Treatment given: Therapeutic agents: Bortezomib + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,075 days (2.9 years); Days to treatment end: 1,155 days (3.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Daratumumab; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,161 days (3.2 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 1,098.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 2.27 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.658 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 200 mg/dL; Immunoglobulin G 29.2 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 5.21 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 226 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.6 mmol/L; Albumin 45 g/L; Total Protein 9.6 g/dL; Glucose 6.93 mmol/L.
- Day 78 (ECOG 0): M Protein 1.37 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.653 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 27 mg/dL; Immunoglobulin G 17.3 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 5.52 mmol/L; Leukocytes 2.8 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 145 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 7.6 g/dL; Glucose 8.03 mmol/L.
- Day 166 (ECOG 0): M Protein 1.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.99 mg/dL; Immunoglobulin G 15.3 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.2 mmol/L; Albumin 33 g/L; Total Protein 6.7 g/dL; Glucose 10.9 mmol/L.
- Day 257 (ECOG 0): M Protein 1.39 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 14.1 mg/dL; Immunoglobulin G 19.9 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 186 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.38 mmol/L; Albumin 40 g/L; Total Protein 7.7 g/dL; Glucose 9.57 mmol/L.
- Day 356 (ECOG 0): M Protein 0.93 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.799 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.51 mg/dL; Immunoglobulin G 14.2 g/L; Immunoglobulin A 0.28 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.1 µg/mL; Lactate Dehydrogenase 2.2 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 164 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.2 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 11.9 mmol/L.
- Day 454: M Protein 0.97 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.89 mg/dL; Immunoglobulin G 13.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.19 g/L; Hemoglobin 5.7 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 181 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 11.4 mmol/L.
- Day 503 (ECOG 0): M Protein 0.81 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.43 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.11 g/L; Hemoglobin 4.84 mmol/L; Leukocytes 1.7 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 8.36 mmol/L.
- Day 573 (ECOG 1): Hemoglobin 5.58 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 166 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 6.1 g/dL; Glucose 14.6 mmol/L.
- Day 685: M Protein 0.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.08 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.46 mg/dL; Immunoglobulin G 12.5 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 77 ×10⁹/L; Creatinine 189 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.2 mmol/L; Albumin 37 g/L; Total Protein 6.5 g/dL; Glucose 12.9 mmol/L.
- Day 776 (ECOG 1): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 9.74 mg/dL; Immunoglobulin G 14.4 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.2 g/L; Lactate Dehydrogenase 9.77 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 176 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.4 g/dL; Glucose 16 mmol/L.
- Day 846 (ECOG 1): M Protein 0.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.2 mg/dL; Immunoglobulin G 14 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 4.9 mmol/L; Leukocytes 2.6 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 82 ×10⁹/L; Creatinine 157 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.08 mmol/L; Albumin 35 g/L; Total Protein 6.4 g/dL; Glucose 8.58 mmol/L.
- Day 947: M Protein 0.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.867 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.26 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.12 g/L; Hemoglobin 5.15 mmol/L; Leukocytes 2.5 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 128 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.05 mmol/L; Albumin 36 g/L; Total Protein 5.5 g/dL; Glucose 10.9 mmol/L.
- Day 1,078: M Protein 1.07 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.555 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.7 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 8.93 mmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 6.7 g/dL; Glucose 11.6 mmol/L.

Other clinical attributes
- Day 1: Weight: 96 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1744_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1744_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
